Gene-level copy-number profile of specimen HCM-BROD-1127-C15-85B from HCMI case HCM-BROD-1127-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 45.4 years (16,577 days).
Specimen HCM-BROD-1127-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20646d5b-ca97-4a1d-a3d7-7bbb25e1be62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1127-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/e577bfb1-c3bb-48bf-aaec-12d684ce36ff

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 1,508; copy number 2: 10,735; copy number 3: 21,896; copy number 4: 16,849; copy number 5: 6,021; copy number 6: 876; copy number 7: 169; copy number 8: 149; copy number 9: 80; copy number 10: 33; copy number 11: 31; copy number 12: 26; copy number 13: 112; copy number 14: 72; copy number 16: 63; copy number 17: 36; copy number 18: 25; copy number 19: 11; copy number 26: 64; copy number 31: 37; copy number 32: 38; copy number 35: 31; copy number 43: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 959 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,915,439–244,451,909, 82 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:246,509,038–248,527,337, 102 genes, copy number 8 (broad region; genes not listed).
- chr2:7,141,227–9,018,899, 23 genes, copy number 8–9: RN7SKP112, AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2, LINC00299, U91324.1, LINC01814, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25.
- chr6:27,247,701–27,596,517, 16 genes, copy number 14–43: PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P.
- chr6:37,353,979–38,154,624, 15 genes, copy number 32: RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:41,764,292–43,786,487, 86 genes, copy number 16–32 (broad region; genes not listed).
- chr6:97,283,303–98,400,869, 1 gene, copy number 7 (within-gene range 5–7): AL589740.1.
- chr6:98,024,531–107,115,515, 82 genes, copy number 7–12 (broad region; genes not listed).
- chr6:119,159,297–120,015,257, 5 genes, copy number 14: AL022722.2, MAN1A1, AL022722.1, RNU6-194P, MIR3144.
- chr8:6,044,353–8,049,267, 101 genes, copy number 13 (broad region; genes not listed).
- chr8:8,228,595–8,782,479, 11 genes, copy number 14: FAM86B3P, ALG1L13P, PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, CLDN23, AC087269.1.
- chr8:10,606,349–13,742,781, 111 genes, copy number 13–26 (broad region; genes not listed).
- chr8:36,378,069–36,779,209, 1 gene, copy number 17 (within-gene range 2–17): AC090809.1.
- chr8:36,764,445–38,099,931, 35 genes, copy number 17: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2.
- chr14:51,750,560–51,979,342, 8 genes, copy number 14 (within-gene range 6–14): AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2.
- chr14:52,004,803–52,069,228, 1 gene, copy number 14 (within-gene range 6–14): NID2.
- chr14:52,267,698–52,791,668, 11 genes, copy number 14: PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3.
- chr14:52,792,875–52,820,034, 2 genes, copy number 14: AL139317.1, AL139317.2.
- chr14:53,685,139–58,551,297, 97 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr14:59,919,423–61,083,733, 31 genes, copy number 11: AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6.
- chr15:60,347,134–60,630,637, 6 genes, copy number 7 (within-gene range 5–7): ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1.
- chr15:60,529,973–60,558,401, 2 genes, copy number 7 (within-gene range 5–7): AC107241.1, CYCSP38.
- chr16:8,276,263–8,590,193, 7 genes, copy number 7: AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114.
- chr16:8,892,097–9,518,325, 11 genes, copy number 7–8 (within-gene range 5–8): USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195.
- chr16:11,547,722–12,574,287, 23 genes, copy number 7–10 (within-gene range 5–10): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2.
- chr19:12,763,003–12,872,740, 1 gene, copy number 31 (within-gene range 2–31): HOOK2.
- chr19:12,791,486–12,793,315, 1 gene, copy number 31 (within-gene range 2–31): JUNB.
- chr19:12,802,031–14,572,066, 87 genes, copy number 14–35 (within-gene range 2–35) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
